Gene-level copy-number profile of tumor specimen HCM-WCMC-0952-C34-01A from HCMI case HCM-WCMC-0952-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Large cell neuroendocrine carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 74.0 years (27,036 days).
Specimen HCM-WCMC-0952-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f7d412c-da17-4d90-ad48-5b61dad01b5c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0952-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,265 have no estimate.
https://portal.gdc.cancer.gov/files/5aba9f1e-324c-459c-aa9c-b8b8abdd5442

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 31; copy number 2: 977; copy number 3: 10,854; copy number 4: 18,622; copy number 5: 16,960; copy number 6: 4,164; copy number 7: 2,813; copy number 8: 2,371; copy number 9: 96; copy number 10: 1,265; copy number 11: 127; copy number 12: 37; copy number 15: 2; copy number 17: 5.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,336,429–25,337,465, 1 gene (within-gene range 0–1): AL928711.1.
- chr1:31,790,422–31,816,051, 1 gene (within-gene range 0–4): SPOCD1.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–4): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr6:11,861,626–11,862,970, 1 gene: AMD1P4.
- chr9:5,096,666–5,114,804, 8 genes (within-gene range 0–2): MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2.
- chr10:57,955,295–58,106,879, 3 genes: AC006484.1, MRPS35P3, AC026884.1.
- chr10:108,708,539–108,849,561, 2 genes: LINC02661, MAPKAPK5P1.
- chr13:87,607,907–87,618,740, 2 genes (within-gene range 0–3): AL355578.1, MIR4500.
- chr16:90,102,271–90,178,344, 4 genes (within-gene range 0–3): FAM157C, AC133919.1, AC133919.2, RNU6-355P.
- chr16:90,174,062–90,175,865, 1 gene (within-gene range 0–1): CICP25.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,532 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:631,074–632,616, 2 genes, copy number 17 (within-gene range 4–17): MTCO1P12, AC114498.2.
- chr1:633,535–634,922, 3 genes, copy number 17 (within-gene range 4–17): MTATP8P1, MTATP6P1, MTCO3P12.
- chr3:186,842,704–188,890,671, 30 genes, copy number 10: ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28.
- chr3:189,631,389–190,449,876, 11 genes, copy number 10: TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207.
- chr3:191,199,241–196,082,096, 109 genes, copy number 10 (broad region; genes not listed).
- chr3:196,867,856–197,646,017, 21 genes, copy number 9: SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3.
- chr4:7,192,538–7,742,836, 1 gene, copy number 9 (within-gene range 7–9): SORCS2.
- chr4:7,430,285–7,460,118, 2 genes, copy number 9: PSAPL1, MIR4274.
- chr4:37,699,895–38,139,175, 9 genes, copy number 9 (within-gene range 7–9): Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2.
- chr8:37,695,782–39,284,917, 55 genes, copy number 10–12: ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10.
- chr8:74,984,505–140,458,579, 859 genes, copy number 10–11 (broad region; genes not listed).
- chr8:140,657,900–145,066,685, 191 genes, copy number 10–11 (broad region; genes not listed).
- chr9:61,642,383–61,662,690, 2 genes, copy number 15: Y_RNA, AL935212.1.
- chr12:45,718,046–48,529,897, 93 genes, copy number 10 (broad region; genes not listed).
- chr12:52,205,392–52,886,385, 50 genes, copy number 10: LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78, RPL7P41.
- chr12:53,708,517–54,610,462, 61 genes, copy number 9 (broad region; genes not listed).
- chr12:57,615,280–57,984,761, 31 genes, copy number 12 (within-gene range 8–12): AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr20:13,785,007–13,996,443, 2 genes, copy number 9 (within-gene range 7–9): NDUFAF5, SEL1L2.

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
